Somatic mutation profile of tumor specimen TCGA-44-6147-01A (aliquot TCGA-44-6147-01A-11D-A271-08) from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7428d58-9e53-472c-8389-a812480e0686.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6147-10A (Blood Derived Normal), aliquot TCGA-44-6147-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7372ac4c-0221-4164-9dee-e772286dfae3

The open-access MAF lists 206 somatic variants for this specimen: 147 protein-altering or splice-affecting, 58 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 58, Nonsense Mutation 8, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 44/164 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.1671A>C p.K557N | Missense Mutation (SNP) | VAF 88/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61660186; called by muse, mutect2, varscan2
- ADAM18 | c.1703C>A p.T568K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV55856001; called by muse, mutect2, varscan2
- ADCY10 | c.4345C>G p.L1449V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63239583, COSV63240944, COSV63245296; called by muse, mutect2
- ADGRF2 | c.616T>A p.W206R (on ENST00000296862 / NM_001368115.2; = p.W138R on NM_153839.7) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57292367; called by muse, mutect2, varscan2
- ALMS1 | c.2445G>T p.E815D | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.106); catalogued as COSV100041528; called by muse, mutect2, varscan2
- ASB10 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV52000955; called by muse, mutect2, varscan2
- ATRX | c.5257A>G p.N1753D | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64884374; called by muse, mutect2, varscan2
- BRINP2 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV64178386; called by muse, mutect2
- BRWD3 | c.2690G>T p.R897M | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100955771; called by muse, mutect2
- CARD14 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs202094920, COSV60126797; ClinVar: likely benign; called by muse, mutect2, varscan2
- CASZ1 | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199630871, COSV59741527; called by muse, mutect2, varscan2
- CCDC167 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447117920; called by muse, mutect2, varscan2
- CCDC73 | c.1835A>G p.E612G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as COSV58805356; called by muse, mutect2, varscan2
- CD101 | c.1473G>T p.W491C | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as COSV99869248; called by muse, mutect2, varscan2
- CD101 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as COSV99869256; called by muse, mutect2, varscan2
- CD93 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV55669140; called by muse, mutect2
- CDH6 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); catalogued as COSV54068746; called by muse, mutect2, varscan2
- CDHR2 | c.2042T>A p.V681D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56145998; called by muse, mutect2, varscan2
- CEP89 | c.2303G>T p.G768V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59862509; called by muse, varscan2
- CEP89 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99993196; called by muse, varscan2
- CNTN1 | c.703C>A p.R235= | Splice Region (SNP) | VAF 18/127 reads (14%) | catalogued as COSV100751086, COSV61638587; called by muse, mutect2, varscan2
- COL23A1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66799365; called by muse, mutect2, varscan2
- CPA4 | c.277G>T p.D93Y | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55985261; called by muse, mutect2, varscan2
- CPT1A | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55761679; called by muse, mutect2, varscan2
- CSMD3 | c.7846G>T p.G2616W (on ENST00000297405 / NM_001363185.1; = p.G2512W on NM_052900.3) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52331340; called by muse, mutect2, varscan2
- CTNNA1 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); catalogued as COSV57081955; called by muse, mutect2, varscan2
- CTTNBP2 | c.2961T>G p.D987E | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV50484331; called by muse, mutect2, varscan2
- CYTH1 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV63123819; called by muse, mutect2, varscan2
- DCLK1 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55213373; called by muse, mutect2, varscan2
- DCLK3 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV69364876; called by muse, mutect2, varscan2
- EGFR | c.2305G>T p.V769L | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs147149347, COSV51802272, COSV51811749; ClinVar: uncertain significance; called by muse, mutect2
- EPDR1 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV52258762, COSV52262160; called by muse, mutect2, varscan2
- EPPK1 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV73262240; called by muse, mutect2
- EXOC4 | c.2117A>T p.D706V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as COSV54124828; called by muse, mutect2, varscan2
- FAM83B | c.1485G>T p.W495C | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV60927347; called by muse, mutect2, varscan2
- FFAR1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV99322956; called by muse, mutect2, varscan2
- FGF4 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51449277; called by muse, mutect2, varscan2
- FLG | c.7423G>T p.G2475* | Nonsense Mutation (SNP) | VAF 336/765 reads (44%) | catalogued as COSV64250568; called by muse, mutect2, varscan2
- FMN2 | c.2523C>A p.H841Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV60456169; called by muse, mutect2, varscan2
- FOXL1 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100206133; called by muse, mutect2, varscan2
- FSCB | c.2296G>T p.A766S | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as rs1246242313, COSV100468972; called by muse, mutect2, varscan2
- FSHR | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.522); catalogued as COSV58623451; called by muse, mutect2
- GABRA6 | c.523G>C p.G175R | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896119; called by muse, mutect2, varscan2
- GPR142 | c.1126G>A p.V376I | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs199997380, COSV59518721, COSV59519491, COSV99046011; called by muse, mutect2, varscan2
- GZMA | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57057915; called by muse, mutect2, varscan2
- H6PD | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV66232499; called by muse, mutect2, varscan2
- HLTF | c.2122C>G p.L708V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as rs1209383794, COSV59503908; called by muse, mutect2, varscan2
- HMCN1 | c.13693delinsTT p.G4565Lfs*17 | Frame Shift Ins (INS) | VAF 12/67 reads (18%) | catalogued as COSV99623534; called by mutect2*, pindel, varscan2*
- IFNLR1 | c.1113G>T p.R371S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59527722; called by muse, mutect2, varscan2
- IGKV3-11 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2
- ITGA8 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65229184; called by muse, mutect2, varscan2
- ITGA8 | c.1150G>T p.G384W | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65225821; called by muse, mutect2, varscan2
- ITIH6 | c.2668C>A p.P890T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV54495150; called by muse, mutect2, varscan2
- KCNJ6 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55713174, COSV55724009; called by muse, mutect2, varscan2
- KCTD19 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV58575473; called by muse, mutect2, varscan2
- KHDC4 | c.845A>C p.E282A | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64165881; called by muse, mutect2
- KRTAP10-3 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100552310, COSV59959098; called by muse, mutect2, varscan2
- LAMB4 | c.3890C>A p.S1297Y | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV52732020; called by muse, mutect2, varscan2
- LUZP4 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782164761, COSV64218745; called by muse, mutect2
- MAP10 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV69365164; called by muse, mutect2
- MAP2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV52309380; called by muse, mutect2, varscan2
- MEIS3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV58985076, COSV58985310; called by muse, varscan2
- MGAM | c.1230G>T p.Q410H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72075973; called by muse, mutect2, varscan2
- MMEL1 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV56526708; called by muse, mutect2, varscan2
- MSH4 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV54213468; called by muse, mutect2, varscan2
- MTMR14 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM065043, COSV56004553, COSV56007889; called by muse, mutect2, varscan2
- MUC17 | c.11840C>A p.T3947N | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs1454428134, COSV60305354; called by muse, mutect2, varscan2
- MUC5B | c.9230C>A p.T3077N | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs990420468; called by muse, mutect2
- MYO7B | c.1941C>A p.C647* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV101267952; called by muse, mutect2, varscan2
- NELL2 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61586363; called by muse, mutect2
- NKX2-5 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs746315645; called by muse, mutect2, varscan2
- NTNG2 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs529755045, COSV62369093; called by muse, mutect2
- OPRL1 | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as rs767233709, COSV61093080; called by muse, mutect2, varscan2
- OR2M4 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV60709843; called by muse, mutect2, varscan2
- OR5T2 | c.236T>G p.M79R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57591116; called by muse, mutect2
- OR6C2 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs141026850; called by muse, mutect2, varscan2
- PARM1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs34305542; called by muse, varscan2
- PCDH11X | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53508284; called by muse, mutect2, varscan2
- PCDH19 | c.428G>T p.S143I | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as COSV55272220; called by muse, mutect2
- PCDHA5 | c.2226C>A p.S742R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as rs1210626259, COSV100972164; called by muse, mutect2, varscan2
- PDE1B | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54496708; called by muse, mutect2, varscan2
- PEX1 | c.473-2A>T p.X158_splice | Splice Site (SNP) | VAF 5/38 reads (13%) | catalogued as COSV50421750; called by muse, mutect2
- PFKP | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101127029; called by muse, mutect2
- PHF20 | c.2232G>C p.Q744H | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV64978119; called by muse, mutect2, varscan2
- PLPPR4 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV64567841; called by muse, mutect2, varscan2
- POTEF | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV62543034; called by muse, mutect2
- PPM1D | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.246); catalogued as COSV59958225; called by muse, mutect2, varscan2
- PREX2 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs751712561, COSV55748519, COSV99907655; called by muse, mutect2
- PRRC2C | c.4617A>T p.E1539D (on ENST00000367742; = p.E1537D on NM_015172.4) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58914159; called by muse, mutect2, varscan2
- PTPRN2 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67061108; called by muse, mutect2, varscan2
- RAB3C | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs764132162, COSV51442889; called by muse, mutect2, varscan2
- ROBO2 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs571504400, COSV59942096; called by muse, mutect2, varscan2
- SETX | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56395572; called by muse, mutect2, varscan2
- SKIV2L | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61715220; called by muse, mutect2, varscan2
- SMARCB1 | c.394G>C p.E132Q (on ENST00000263121; = p.E178Q on NM_003073.5) | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV54096006; called by muse, mutect2
- SMC2 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV53965317; called by muse, mutect2
- SNX13 | c.2333T>C p.L778P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247450792, COSV68068407; called by muse, mutect2
- SORCS3 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.949); catalogued as COSV63826429; called by muse, mutect2, varscan2
- SYTL4 | c.519G>C p.Q173H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.332); catalogued as COSV52172260; called by muse, mutect2, varscan2
- TBC1D9B | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100783454; called by muse, mutect2, varscan2
- TEX101 | c.328G>C p.E110Q (on ENST00000598265 / NM_001130011.3; = p.E128Q on NM_031451.4) | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.43); catalogued as COSV53663326; called by muse, mutect2
- TG | c.6796C>A p.Q2266K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV55073351; called by muse, mutect2
- TLR4 | c.582C>G p.D194E (on ENST00000355622 / NM_138554.5; = p.D154E on NM_003266.4) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV62924355; called by muse, mutect2, varscan2
- TMEM120A | c.564G>A p.R188= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as rs782743658, COSV100115510; called by muse, mutect2, varscan2
- TMEM135 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV59707117; called by muse, mutect2
- TRIM22 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66090672, COSV66091936; called by muse, mutect2, varscan2
- TSGA10 | c.1668G>C p.Q556H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61825934; called by muse, mutect2
- TSGA10 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV61825938; called by muse, mutect2
- TSNARE1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.175); catalogued as COSV56184735; called by muse, mutect2, varscan2
- TULP1 | c.1546C>A p.L516I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57694001; called by muse, mutect2, varscan2
- UROC1 | c.1811G>C p.G604A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760134412, COSV52039916; called by muse, mutect2, varscan2
- VWA3B | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV68247114; called by muse, mutect2, varscan2
- WDR3 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs780090748, COSV60469269; called by muse, mutect2, varscan2
- ZBED9 | c.2452A>T p.S818C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV71729802; called by muse, mutect2, varscan2
- ZDBF2 | c.1726T>A p.S576T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65630528; called by muse, mutect2, varscan2
- ZNF226 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV56197085; called by muse, mutect2, varscan2
- ZNF474 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as COSV56947867; called by muse, mutect2, varscan2
- ZZEF1 | c.2768A>G p.K923R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1291056581, COSV67560446; called by muse, mutect2, varscan2
- ADGRG4 | c.7730G>A p.G2577D | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- ANAPC5 | c.1111T>A p.F371I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- DCN | c.250dup p.T84Nfs*19 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- DMWD | c.1088G>C p.R363P | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNA2 | c.1958_1976del p.G653Vfs*4 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel
- GGNBP2 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- HMCN1 | c.13692dup p.G4565Wfs*17 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | called by mutect2, varscan2
- HOATZ | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ16 | c.254G>A p.W85* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- KCNT1 | c.1132C>A p.P378T (on ENST00000488444; = p.P397T on NM_020822.3) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MUC6 | c.2131del p.Q711Kfs*41 | Frame Shift Del (DEL) | VAF 38/188 reads (20%) | called by mutect2, varscan2
- MUC6 | c.2130C>A p.N710K | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- MYO18B | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR3A2 | c.56C>A p.A19D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- OR5B3 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); called by muse, mutect2
- R3HDM1 | c.3037G>A p.A1013T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- RPGRIP1 | c.2250C>A p.Y750* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- SCN2A | c.1840C>T p.P614S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SMC3 | c.1827G>A p.M609I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); called by muse, mutect2
- SPATA31A1 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 84/404 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, varscan2
- SPATA31A3 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- TNNT3 | c.374A>T p.E125V (on ENST00000397301 / NM_001367846.1; = p.E114V on NM_006757.4) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRBV24-1 | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRBV3-1 | c.336C>G p.S112R | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM45 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2
- TRRAP | c.872del p.L291* | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.8602_8633del p.S2868Gfs*7 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | called by mutect2, pindel
- ABHD5 | c.396G>A p.V132= | Silent (SNP) | VAF 53/169 reads (31%) | catalogued as rs373148191, COSV50007116; called by muse, mutect2, varscan2
- ALG10 | c.1125A>T p.P375= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV56794348; called by muse, mutect2, varscan2
- ANK2 | c.8832C>A p.T2944= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as COSV52191080; called by muse, mutect2, varscan2
- ANXA6 | c.879C>T p.F293= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs781611897, COSV100636816; called by muse, mutect2, varscan2
- ARID1A | c.5334A>G p.E1778= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs375160070; called by muse, mutect2, varscan2
- ATP2B4 | c.96C>A p.L32= | Silent (SNP) | VAF 105/263 reads (40%) | catalogued as COSV58175372, COSV58184476; called by muse, mutect2, varscan2
- ATRNL1 | c.759C>T p.C253= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs200296037, COSV61814876; called by muse, mutect2, varscan2
- BEX3 | c.150C>A p.A50= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as COSV100244237; called by muse, mutect2
- BRINP2 | c.204T>C p.A68= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV64180577; called by muse, mutect2, varscan2
- CACNA1S | c.1920C>T p.Y640= | Silent (SNP) | VAF 45/363 reads (12%) | catalogued as COSV62944214; called by muse, mutect2, varscan2
- CDIPT | c.54G>A p.R18= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99570137; called by muse, mutect2
- CFAP46 | c.6015A>T p.T2005= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV54160162; called by muse, mutect2, varscan2
- CHRDL2 | c.76C>A p.R26= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- CNTN5 | c.2598G>A p.V866= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV54361132; called by muse, mutect2, varscan2
- COL19A1 | c.3279T>C p.S1093= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV59589824; called by muse, mutect2, varscan2
- COL22A1 | c.4308G>A p.E1436= | Silent (SNP) | VAF 66/123 reads (54%) | catalogued as COSV57347163, COSV57362679; called by muse, mutect2, varscan2
- CSMD2 | c.1825C>T p.L609= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs769998248, COSV53957048; called by muse, mutect2, varscan2
- CTSG | c.99C>A p.P33= | Silent (SNP) | VAF 89/214 reads (42%) | catalogued as COSV53537038; called by muse, mutect2, varscan2
- DCHS1 | c.1728C>A p.P576= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100201653; called by muse, mutect2
- DISP2 | c.2352C>A p.G784= | Silent (SNP) | VAF 45/155 reads (29%) | catalogued as COSV51145547; called by muse, mutect2, varscan2
- DUSP19 | c.259C>T p.L87= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100700210; called by muse, mutect2, varscan2
- ESPL1 | c.766T>C p.L256= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV57763688; called by muse, mutect2
- FEZ1 | c.1092A>T p.T364= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- FLVCR2 | c.93C>A p.P31= | Silent (SNP) | VAF 123/226 reads (54%) | catalogued as COSV53163737; called by muse, mutect2, varscan2
- FSCB | c.2295G>T p.V765= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV100468977; called by muse, mutect2, varscan2
- GABRQ | c.1707C>A p.G569= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV64780795, COSV64784100; called by muse, mutect2, varscan2
- GBP5 | c.42C>T p.I14= | Silent (SNP) | VAF 21/218 reads (10%) | catalogued as rs372467199, COSV100599978; called by muse, mutect2, varscan2
- GRM7 | c.297G>C p.V99= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV63173646; called by muse, mutect2, varscan2
- HTR1D | c.246C>A p.T82= | Silent (SNP) | VAF 31/195 reads (16%) | catalogued as COSV100024725; called by muse, mutect2, varscan2
- ISL1 | c.460C>A p.R154= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV57935903; called by muse, mutect2, varscan2
- KCNAB1 | c.930G>A p.G310= (on ENST00000490337 / NM_172160.3; = p.G299= on NM_003471.3) | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV100203986; called by muse, mutect2, varscan2
- KPRP | c.36G>T p.P12= | Silent (SNP) | VAF 52/107 reads (49%) | catalogued as rs761781923, COSV64222236, COSV64223096; called by muse, mutect2, varscan2
- LILRB5 | c.1155G>A p.V385= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1300117140; called by muse, mutect2, varscan2
- LRP1B | c.9885C>A p.T3295= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV67260856, COSV67279065; called by muse, mutect2, varscan2
- LSP1 | c.528C>A p.P176= | Silent (SNP) | VAF 33/196 reads (17%) | catalogued as COSV61137836; called by muse, mutect2, varscan2
- LUZP2 | c.915A>C p.A305= | Silent (SNP) | VAF 29/109 reads (27%) | catalogued as COSV61219524; called by muse, mutect2, varscan2
- MMP3 | c.1128C>T p.I376= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV55408311; called by muse, mutect2
- MSI2 | c.378A>C p.V126= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV52369308; called by muse, mutect2, varscan2
- NEUROD4 | c.828C>G p.S276= | Silent (SNP) | VAF 31/216 reads (14%) | catalogued as COSV54474350, COSV54474648; called by muse, mutect2, varscan2
- OR1J2 | c.486C>A p.L162= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as COSV58945409; called by muse, mutect2, varscan2
- OR2M3 | c.495C>T p.S165= | Silent (SNP) | VAF 22/321 reads (7%) | catalogued as COSV71759314; called by muse, mutect2
- OR4M1 | c.453G>T p.G151= | Silent (SNP) | VAF 97/242 reads (40%) | catalogued as COSV60063785; called by muse, mutect2, varscan2
- OR7G1 | c.138C>G p.L46= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as COSV53319131, COSV99528779; called by muse, mutect2, varscan2
- OR8H2 | c.432C>A p.L144= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as rs1167909567, COSV57947637; called by muse, mutect2
- PCDHA8 | c.60C>A p.L20= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV65340726; called by muse, mutect2, varscan2
- PCDHB11 | c.2157G>T p.A719= | Silent (SNP) | VAF 59/231 reads (26%) | catalogued as COSV61314045, COSV61314188; called by muse, mutect2, varscan2
- PLA2R1 | c.2544C>T p.L848= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1560166743, COSV51787435; called by muse, mutect2, varscan2
- PNPLA8 | c.1944A>G p.P648= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs771282623, COSV57555046; called by muse, mutect2, varscan2
- PRAMEF1 | c.405A>G p.A135= | Silent (SNP) | VAF 51/303 reads (17%) | catalogued as COSV60019394; called by muse, mutect2, varscan2
- PSG7 | c.321G>T p.L107= | Silent (SNP) | VAF 93/773 reads (12%) | catalogued as COSV68446805; called by muse, mutect2, varscan2
- QPCTL | c.270A>T p.P90= | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as COSV99171222; called by muse, mutect2, varscan2
- RHAG | c.729G>T p.T243= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV57706648; called by muse, mutect2, varscan2
- RIMBP2 | c.1032C>T p.L344= | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs1252958705, COSV55485264; called by muse, mutect2
- SAMSN1 | c.633G>T p.V211= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as COSV53478106; called by muse, mutect2, varscan2
- TAF9B | c.21G>T p.A7= | Silent (SNP) | VAF 11/215 reads (5%) | catalogued as COSV59372453; called by muse, mutect2
- TNR | c.1275G>A p.T425= | Silent (SNP) | VAF 22/225 reads (10%) | catalogued as rs781713010, COSV54872166; called by muse, mutect2
- WSCD1 | c.1254T>A p.I418= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1392012900, COSV58498706; called by muse, mutect2, varscan2
- ZNF79 | c.237T>G p.L79= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV61071986; called by muse, mutect2, varscan2
- NFASC | c.2471-1392C>T | Intron (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
